Somatic mutation profile of tumor specimen MMRF_2664_1_BM_CD138pos (aliquot MMRF_2664_1_BM_CD138pos_T1_KHS5U_L13780) from MMRF case MMRF_2664, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.2 years (23,433 days).
Specimen MMRF_2664_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4e65923-df07-4456-9089-8e393e3f6cb6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2664_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2664_1_PB_WBC_C3_KHS5U_L13781; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb87824d-2fa8-43fc-80fe-57e39f17fb64

The open-access MAF lists 179 somatic variants for this specimen: 77 protein-altering or splice-affecting, 18 silent, 84 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, 3'UTR 49, Intron 21, Silent 18, Splice Site 8, RNA 6, 5'UTR 5, Nonsense Mutation 2, Frame Shift Del 2, 3'Flank 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA2C | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 254/283 reads (90%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV57468145; called by muse, mutect2, varscan2
- ANKRD55 | c.1568G>T p.R523L | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); catalogued as rs141966247; called by muse, mutect2, varscan2
- DSEL | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 107/284 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100026058; called by muse, mutect2, varscan2
- DUSP2 | c.378C>G p.Y126* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | catalogued as rs1364514451, COSV56619695; called by muse, mutect2, varscan2
- FAM71F1 | c.236G>C p.S79T | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV59373193; called by muse, mutect2, varscan2
- GRID2 | c.1877C>T p.T626M | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs769386426, COSV99938421; called by muse, mutect2, varscan2
- IGHE | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.031); catalogued as rs375503727; called by muse, mutect2, varscan2
- IGLV3-1 | c.332G>C p.S111T | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as rs563308501; called by muse, mutect2, varscan2
- LAMB2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378409559, COSV59735860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MPHOSPH10 | c.365T>C p.I122T | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs971903349; called by muse, mutect2
- MUC3A | c.8096T>C p.I2699T | Missense Mutation (SNP) | VAF 149/846 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.014); catalogued as rs772901962; called by muse, mutect2, varscan2
- NCKAP5 | c.3816A>C p.K1272N | Missense Mutation (SNP) | VAF 105/223 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58425529; called by muse, mutect2, varscan2
- NID1 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs376540541; called by muse, mutect2, varscan2
- NLN | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs774658110; called by muse, mutect2, varscan2
- NOVA1 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746531696, COSV57472771; called by muse, mutect2, varscan2
- OR10A5 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 180/277 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs760596192; called by muse, mutect2, varscan2
- PCDHA7 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 17/293 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.009); catalogued as rs782034445, COSV65342515; called by muse, mutect2
- RPP38 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs1340886584; called by muse, mutect2
- RTN1 | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.085); catalogued as rs1167810945; called by muse, mutect2, varscan2
- SLC6A11 | c.955G>T p.A319S | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.864); catalogued as COSV54400544; called by muse, mutect2, varscan2
- SLCO1B3 | c.360-3_362del p.X120_splice | Splice Site (DEL) | VAF 14/32 reads (44%) | catalogued as rs772663115; ClinVar: uncertain significance; called by mutect2, pindel
- SPAG17 | c.828A>C p.E276D | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs565999997; called by muse, varscan2
- SPECC1L | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs201626909; called by muse, mutect2
- ST6GAL2 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | PolyPhen benign (0.006); catalogued as rs369427384; called by muse, mutect2
- TFAP2B | c.640A>T p.N214Y | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as COSV53827600; called by muse, mutect2
- ZC3H11B | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1475310204; called by mutect2, varscan2
- ACACA | c.86-1G>A p.X29_splice | Splice Site (SNP) | VAF 66/170 reads (39%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.2080-2A>G p.X694_splice | Splice Site (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- AMPD1 | c.1615-1G>T p.X539_splice | Splice Site (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- ASCC3 | c.1943C>A p.S648Y | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRWD3 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1S | c.1231A>G p.I411V | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEMIP | c.1822T>A p.S608T | Missense Mutation (SNP) | VAF 209/357 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CENPF | c.4955C>A p.S1652Y | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CEP250 | c.3241G>C p.E1081Q | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.307); called by muse, mutect2
- COL12A1 | c.2528A>G p.Q843R | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- DUSP2 | c.746G>C p.S249T | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.221); called by muse, varscan2
- DUSP2 | c.730+1G>T p.X244_splice | Splice Site (SNP) | VAF 116/256 reads (45%) | called by muse, varscan2
- DUSP2 | c.683A>G p.Q228R | Missense Mutation (SNP) | VAF 138/304 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, varscan2
- ERICH3 | c.2382G>T p.E794D | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ESCO1 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 9/296 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2
- EXOC2 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- GALNT17 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.837); called by muse, mutect2
- GBX1 | c.605G>T p.S202I | Missense Mutation (SNP) | VAF 13/302 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- GDI2 | c.642A>T p.E214D | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by mutect2, varscan2
- GRIN2A | c.4165C>T p.H1389Y | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HPCAL1 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 112/265 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KIAA1210 | c.2027T>G p.L676R | Missense Mutation (SNP) | VAF 67/73 reads (92%) | SIFT tolerated (0.57); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KRT36 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.058); called by muse, mutect2
- LMBR1 | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- LNX1 | c.1536del p.D513Tfs*8 (on ENST00000263925 / NM_001126328.3; = p.D417Tfs*8 on NM_032622.2) | Frame Shift Del (DEL) | VAF 40/183 reads (22%) | called by mutect2, pindel, varscan2
- LRFN5 | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- LRRK2 | c.5017_5020del p.X1673_splice | Splice Site (DEL) | VAF 64/179 reads (36%) | called by mutect2, pindel, varscan2
- MAP4K3 | c.1751A>C p.Y584S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MLNR | c.1039A>G p.S347G | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- MYBBP1A | c.2129A>T p.D710V | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.21); called by muse, mutect2
- MYO1B | c.3118A>G p.S1040G (on ENST00000304164; = p.S982G on NM_012223.5) | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NBEAL2 | c.8237_8238insTAACCCACGTTAAG p.E2747Nfs*4 | Nonsense Mutation (INS) | VAF 80/342 reads (23%) | called by mutect2, pindel*, varscan2*
- PRRC2C | c.6977C>G p.S2326C (on ENST00000367742; = p.S2324C on NM_015172.4) | Missense Mutation (SNP) | VAF 5/133 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PRSS22 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RP1 | c.2558A>T p.K853I | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.706); called by muse, mutect2
- SCN1A | c.1840C>T p.H614Y | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.18); called by muse, mutect2
- SLC51B | c.188+2T>C p.X63_splice | Splice Site (SNP) | VAF 87/134 reads (65%) | called by muse, mutect2, varscan2
- SMARCC2 | c.2686A>T p.M896L | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- SNX5 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNPO2L | c.1184G>A p.R395H (on ENST00000394810 / NM_001114133.3; = p.R171H on NM_024875.5) | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- TENM2 | c.892T>C p.S298P (on ENST00000518659 / NM_001122679.2; = p.S107P on NM_001080428.3) | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TENT5C | c.723dup p.G242Rfs*42 | Frame Shift Ins (INS) | VAF 23/121 reads (19%) | called by mutect2, pindel, varscan2
- TNXB | c.8137G>T p.V2713L (on ENST00000647633; = p.V2466L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.905); called by muse, mutect2
- TPT1 | c.516+2T>C p.X172_splice | Splice Site (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- TSPEAR | c.1230G>C p.K410N | Missense Mutation (SNP) | VAF 5/126 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by muse, mutect2
- UBE3A | c.1545A>C p.Q515H | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- UNC13C | c.2925del p.A976Lfs*2 | Frame Shift Del (DEL) | VAF 30/287 reads (10%) | called by mutect2, pindel, varscan2
- VIT | c.752A>G p.D251G | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- WDR70 | c.1412A>T p.D471V | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZBTB26 | c.475C>G p.P159A | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF580 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- APOL2 | c.729G>A p.P243= | Silent (SNP) | VAF 105/238 reads (44%) | catalogued as rs996251871; called by muse, varscan2
- ARAP3 | c.2958G>A p.E986= | Silent (SNP) | VAF 132/398 reads (33%) | called by muse, mutect2, varscan2
- CSMD3 | c.9834C>T p.T3278= (on ENST00000297405 / NM_001363185.1; = p.T3109= on NM_052900.3) | Silent (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- DMRTA2 | c.819C>T p.G273= | Silent (SNP) | VAF 28/141 reads (20%) | called by muse, mutect2, varscan2
- DYNC2I1 | c.2589A>C p.T863= | Silent (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- EPS8L2 | c.1029C>G p.L343= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as COSV100585285, COSV100585325; called by muse, mutect2
- FHOD1 | c.1164G>A p.P388= | Silent (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- GATA4 | c.765C>T p.I255= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs760250504; called by muse, mutect2, varscan2
- KL | c.1794C>T p.D598= | Silent (SNP) | VAF 107/209 reads (51%) | called by muse, mutect2, varscan2
- LRRN3 | c.24T>A p.I8= | Silent (SNP) | VAF 321/518 reads (62%) | called by muse, mutect2, varscan2
- MUC4 | c.14337C>T p.D4779= (on ENST00000463781 / NM_018406.7; = p.D543= on NM_004532.6) | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as rs1033036147; called by muse, mutect2, varscan2
- PHF24 | c.732A>G p.Q244= | Silent (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- PLEKHA1 | c.984T>C p.S328= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- RANBP9 | c.1206T>C p.A402= | Silent (SNP) | VAF 61/151 reads (40%) | called by muse, mutect2, varscan2
- SLC30A10 | c.117C>T p.S39= | Silent (SNP) | VAF 13/286 reads (5%) | called by muse, mutect2
- STMN4 | c.45G>T p.L15= | Silent (SNP) | VAF 9/271 reads (3%) | called by muse, mutect2
- SVIL | c.363G>T p.G121= | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as COSV63443320; called by muse, mutect2, varscan2
- VCAN | c.5754G>C p.G1918= | Silent (SNP) | VAF 23/398 reads (6%) | catalogued as rs182828013; called by muse, mutect2
- ABCF3 | c.-5G>C | 5'UTR (SNP) | VAF 53/195 reads (27%) | called by muse, mutect2, varscan2
- ACTA1 | c.*195C>T | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- ADAMDEC1 | c.*546A>G | 3'UTR (SNP) | VAF 20/53 reads (38%) | catalogued as rs373007354; called by muse, mutect2, varscan2
- AGR2 | c.*429G>C | 3'UTR (SNP) | VAF 13/179 reads (7%) | called by muse, mutect2
- AIPL1 | c.*1398G>A | 3'UTR (SNP) | VAF 13/86 reads (15%) | catalogued as rs886053259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKR1D1 | c.*682G>T | 3'UTR (SNP) | VAF 85/135 reads (63%) | catalogued as COSV54341635; called by muse, mutect2, varscan2
- AL353743.4 | n.672A>T | RNA (SNP) | VAF 18/226 reads (8%) | catalogued as rs1489340013; called by muse, mutect2
- ANKRD11 | c.226+4469_226+4470insATGTA | Intron (INS) | VAF 15/39 reads (38%) | called by mutect2, pindel*, varscan2
- APBA1 | c.*99G>A | 3'UTR (SNP) | VAF 16/240 reads (7%) | catalogued as rs1454442182; called by muse, mutect2
- ARSK | c.*850C>G | 3'UTR (SNP) | VAF 14/214 reads (7%) | catalogued as rs997588953; called by muse, mutect2
- BOC | c.376+28A>G | Intron (SNP) | VAF 67/288 reads (23%) | catalogued as rs768293299; called by muse, mutect2, varscan2
- CAPRIN1 | c.*974T>A | 3'UTR (SNP) | VAF 18/59 reads (31%) | catalogued as rs903453074; called by muse, mutect2, varscan2
- CMC1 | c.*230C>T | 3'UTR (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.*909C>T | 3'UTR (SNP) | VAF 11/32 reads (34%) | catalogued as rs1034172267; called by mutect2, varscan2
- CPSF7 | c.273+277C>T | Intron (SNP) | VAF 51/200 reads (26%) | catalogued as rs928712220; called by muse, mutect2, varscan2
- CREBBP | c.*1340G>A | 3'UTR (SNP) | VAF 98/279 reads (35%) | called by muse, mutect2, varscan2
- CTNNA2 | c.102+36017T>G | Intron (SNP) | VAF 43/116 reads (37%) | called by muse, mutect2, varscan2
- CYFIP1 | c.1675-376C>T | Intron (SNP) | VAF 16/55 reads (29%) | catalogued as rs190676598; called by muse, mutect2, varscan2
- EEPD1 | c.*355C>T | 3'UTR (SNP) | VAF 44/168 reads (26%) | catalogued as rs1226786284; called by muse, mutect2, varscan2
- ENOX2 | c.*213A>G | 3'UTR (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- EPHA5 | c.*2178A>C | 3'UTR (SNP) | VAF 39/71 reads (55%) | called by muse, mutect2, varscan2
- EPHB2 | c.*972A>T | 3'UTR (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- FAM102A | c.*2197G>C | 3'UTR (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- FAM189A2 | c.360+36G>T | Intron (SNP) | VAF 87/196 reads (44%) | catalogued as COSV99974679; called by muse, mutect2, varscan2
- GABRA2 | c.187+20416G>T | Intron (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- GRB10 | c.*751G>T | 3'UTR (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- GTPBP1 | c.*2270A>G | 3'UTR (SNP) | VAF 45/102 reads (44%) | catalogued as rs1369648443; called by muse, mutect2, varscan2
- H2AJ | c.-18T>A | 5'UTR (SNP) | VAF 57/125 reads (46%) | called by muse, mutect2, varscan2
- HIPK2 | c.*7212A>G | 3'UTR (SNP) | VAF 16/21 reads (76%) | catalogued as rs1569434989, COSV69209555; called by mutect2, varscan2
- HUNK | c.*240C>T | 3'UTR (SNP) | VAF 6/92 reads (7%) | catalogued as rs1335049316; called by muse, mutect2
- ISL1 | c.*973A>C | 3'UTR (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- KIF1C | c.*2288A>G | 3'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- KIN | c.*75T>G | 3'UTR (SNP) | VAF 62/155 reads (40%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.*379C>A | 3'UTR (SNP) | VAF 11/237 reads (5%) | called by muse, mutect2
- KREMEN1 | chr22:29146390 G>A | 3'Flank (SNP) | VAF 88/181 reads (49%) | catalogued as rs1036645372; called by muse, mutect2, varscan2
- KRTAP19-5 | c.*203T>G | 3'UTR (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- KRTAP20-2 | c.*93T>A | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- KRTAP26-1 | c.-190G>T | 5'UTR (SNP) | VAF 4/65 reads (6%) | called by muse, mutect2
- LINC00587 | n.113A>T | RNA (SNP) | VAF 32/334 reads (10%) | called by muse, mutect2
- MAGI3 | c.*1396T>C | 3'UTR (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- MCTP1 | c.*947T>G | 3'UTR (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2, varscan2
- MMP15 | c.*1380G>T | 3'UTR (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- MMP17 | c.423-299C>T | Intron (SNP) | VAF 91/186 reads (49%) | catalogued as rs377133963; called by muse, mutect2, varscan2
- MPDZ | c.*78T>A | 3'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- NEBL | c.*3145C>A | 3'UTR (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- NLGN4X | c.*1004T>G | 3'UTR (SNP) | VAF 37/40 reads (93%) | called by muse, mutect2, varscan2
- NPAS3 | c.141-1332T>A | Intron (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- NSD2 | c.*2176A>C | 3'UTR (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- NTRK3 | chr15:87876422 T>G | 3'Flank (SNP) | VAF 143/232 reads (62%) | called by muse, mutect2, varscan2
- OFCC1 | n.1671G>T | RNA (SNP) | VAF 55/180 reads (31%) | called by muse, mutect2, varscan2
- OPCML | c.*2165T>G | 3'UTR (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- OR2L1P | n.616dup | RNA (INS) | VAF 107/303 reads (35%) | catalogued as rs1231611778; called by mutect2, pindel, varscan2
- PAFAH1B1 | c.1160-153A>G | Intron (SNP) | VAF 7/15 reads (47%) | catalogued as rs773857822; called by muse, varscan2
- PCYOX1L | c.*443A>G | 3'UTR (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- PDE9A | c.568+185A>G | Intron (SNP) | VAF 8/19 reads (42%) | catalogued as rs758111872; called by muse, mutect2, varscan2
- PPP2R3A | c.*925C>T | 3'UTR (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- PTPN7 | c.-27C>G | 5'UTR (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- PTPRN2 | c.2344+5792G>A | Intron (SNP) | VAF 44/141 reads (31%) | catalogued as rs748348381, COSV67057284; called by muse, mutect2, varscan2
- RAB6B | c.*2296G>A | 3'UTR (SNP) | VAF 10/147 reads (7%) | called by muse, mutect2
- RANBP3 | c.918-112del | Intron (DEL) | VAF 14/22 reads (64%) | called by mutect2, varscan2
- RNF126 | c.134+92G>C | Intron (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- RTN2 | c.1556+110A>C | Intron (SNP) | VAF 26/44 reads (59%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.89-193C>G | Intron (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- SAMD10 | c.*1336A>G | 3'UTR (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- SDC1 | c.*1612G>A | 3'UTR (SNP) | VAF 45/98 reads (46%) | catalogued as rs1014110228; called by muse, mutect2, varscan2
- SENP7 | c.*1424T>G | 3'UTR (SNP) | VAF 50/98 reads (51%) | called by muse, mutect2, varscan2
- SHANK1 | c.*79A>T | 3'UTR (SNP) | VAF 17/178 reads (10%) | called by muse, mutect2
- SLC44A1 | c.*3385A>G | 3'UTR (SNP) | VAF 10/17 reads (59%) | catalogued as rs1229829218; called by muse, mutect2, varscan2
- SLC4A9 | c.2500-74G>A | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2
- SLCO1C1 | c.129+97del | Intron (DEL) | VAF 5/36 reads (14%) | called by pindel, varscan2
- SLITRK2 | c.-1070T>C | 5'UTR (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- TACR3 | c.*2687T>G | 3'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- TASOR2 | c.*639_*640dup | 3'UTR (INS) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- TCOF1 | c.3600+116C>T | Intron (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2465G>A | RNA (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- TGM2 | c.1616-370C>T | Intron (SNP) | VAF 67/155 reads (43%) | catalogued as rs776535753; called by muse, mutect2, varscan2
- TMSB4X | c.-17+111G>A | Intron (SNP) | VAF 70/77 reads (91%) | called by muse, mutect2, varscan2
- TMX4 | c.*182G>C | 3'UTR (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- TNRC18P2 | n.1527C>T | RNA (SNP) | VAF 8/33 reads (24%) | catalogued as rs1456835715; called by muse, mutect2
- TOGARAM1 | c.*487G>A | 3'UTR (SNP) | VAF 36/72 reads (50%) | catalogued as COSV100818322; called by muse, mutect2, varscan2
- VASH2 | chr1:212951491 C>T | 5'Flank (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- XDH | c.*726dup | 3'UTR (INS) | VAF 8/18 reads (44%) | catalogued as rs35595791; called by mutect2, pindel, varscan2
- ZFP42 | c.*109dup | 3'UTR (INS) | VAF 52/239 reads (22%) | called by mutect2, pindel, varscan2
- ZNF138 | c.*597T>A | 3'UTR (SNP) | VAF 6/146 reads (4%) | called by muse, mutect2
